Gene-level copy-number profile of tumor specimen TCGA-06-0132-01A from TCGA case TCGA-06-0132, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.6 years (18,125 days).
Specimen TCGA-06-0132-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.28887e9e-0f53-4240-a1d8-93bab59cfc4a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0132-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b935ce77-a479-41bd-8bde-758dd286f355

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 245; copy number 1: 11,106; copy number 2: 45,454; copy number 3: 3,005; copy number 52: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0132-01A-02D-0236-01): tumor purity 0.28, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 238 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,409,009–32,454,769, 155 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:18,333,726–19,957,996, 83 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–55,572,988, 9 genes, copy number 52 (within-gene range 3–52): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.

Autosomal genes at a single copy (total copy number 1): 8,692. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
